Gene-level copy-number profile of tumor specimen ALCH-B3K0-TTP1-A from ALCHEMIST case ALCH-B3K0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.0 years (25,554 days).
Specimen ALCH-B3K0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0e668659-74db-4ddc-a159-518d7230dd75.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3K0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/af659721-fcd3-435f-9214-8bfde2301b76

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 664; copy number 1: 26,930; copy number 2: 28,252; copy number 3: 2,439; copy number 4: 8; copy number 5: 599; copy number 6: 10; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 146 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,783,787–40,840,452, 2 genes: KCNQ4, RN7SL326P.
- chr1:53,304,536–53,307,462, 1 gene (within-gene range 0–2): AL355483.2.
- chr1:109,249,539–109,275,751, 1 gene: CELSR2.
- chr2:127,535,802–127,681,786, 4 genes: MYO7B, AC010976.2, LIMS2, GPR17.
- chr2:130,151,392–130,190,729, 2 genes: SMPD4, MZT2B.
- chr3:47,562,238–47,580,792, 1 gene: CSPG5.
- chr3:47,802,909–47,850,195, 3 genes (within-gene range 0–1): DHX30, AC026318.1, MIR1226.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:139,684,645–139,844,466, 6 genes: AC008667.1, RNU6-236P, PSD2-AS1, AC008667.3, AC008667.4, PSD2.
- chr5:139,848,290–139,856,389, 1 gene (within-gene range 0–1): AC008667.2.
- chr5:177,357,924–177,516,961, 13 genes: RGS14, SLC34A1, PFN3, F12, GRK6, PRR7-AS1, PRR7, DBN1, AC145098.2, PDLIM7, AC145098.1, DOK3, DDX41.
- chr6:57,919,784–57,930,291, 1 gene: GUSBP4.
- chr7:150,322,639–150,343,346, 4 genes (within-gene range 0–2): ZBED6CL, LRRC61, AC005586.1, RARRES2.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:124,257,606–124,353,307, 3 genes (within-gene range 0–2): NEK6, AL162724.2, AL162724.1.
- chr10:43,077,064–43,130,351, 1 gene: RET.
- chr11:130,404,923–130,476,641, 2 genes: ADAMTS8, ADAMTS15.
- chr15:25,172,635–25,241,827, 38 genes (within-gene range 0–1): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39.
- chr15:40,906,811–40,939,073, 2 genes: AC020661.1, DLL4.
- chr15:85,759,326–85,794,925, 3 genes: KLHL25, MIR1276, AC021739.1.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr16:29,992,330–30,052,978, 5 genes: HIRIP3, INO80E, DOC2A, C16orf92, TLCD3B.
- chr16:49,487,524–49,900,524, 7 genes (within-gene range 0–1): ZNF423, ADAM3B, MRPS21P7, AC027348.2, MRPS21P8, AC027348.1, AC007603.2.
- chr16:58,421,326–58,462,470, 1 gene: LINC02137.
- chr17:997,129–1,003,671, 1 gene (within-gene range 0–1): TIMM22.
- chr17:1,022,476–1,022,559, 1 gene (within-gene range 0–1): MIR3183.
- chr17:3,565,444–3,981,899, 22 genes: TRPV1, AC027796.5, AC027796.3, AC027796.1, SHPK, AC027796.2, CTNS, AC027796.4, TAX1BP3, P2RX5-TAX1BP3, AC132942.1, EMC6, P2RX5, ITGAE, AC116914.2, HASPIN, AC116914.1, NCBP3, CAMKK1, P2RX1, ATP2A3, LINC01975.
- chr18:61,905,255–62,187,118, 1 gene (within-gene range 0–1): PIGN.
- chr20:41,359,962–41,383,107, 2 genes (within-gene range 0–2): EMILIN3, AL031667.1.
- chr20:43,652,523–43,653,291, 1 gene: RPL27AP.
- chr22:43,166,622–43,187,134, 1 gene: TTLL12.
- chr22:43,212,674–43,239,010, 2 genes (within-gene range 0–1): SCUBE1-AS2, Z82214.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 610 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,088,633–242,175,634, 4 genes, copy number 5: LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr5:58,198–40,269,719, 596 genes, copy number 5–9 (broad region; genes not listed).
- chr11:127,204–186,136, 3 genes, copy number 6 (within-gene range 1–6): LINC01001, AC069287.3, RNU6-447P.
- chr16:28,364,700–28,455,356, 6 genes, copy number 6: AC138894.3, EIF3CL, MIR6862-1, CDC37P2, AC138894.4, AC138894.2.
- chr16:28,456,372–28,471,175, 1 gene, copy number 6 (within-gene range 2–6): NPIPB7.

Autosomal genes at a single copy (total copy number 1): 24,603. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
